Somatic mutation profile of tumor specimen 0DVZ1K from CCDI case PBCNGN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.0 years (1,472 days).
Specimen 0DVZ1K: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6639949e-f0a4-4281-a11a-004e83061cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61c099ce-e216-4ec6-977f-18c37c4f678f

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, 3'UTR 4, Intron 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 1055/1339 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM17 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 145/410 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs146033784; called by muse, mutect2, varscan2
- ANXA2 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs770772924; called by muse, mutect2, varscan2
- AQP5 | c.363G>A p.A121= | Splice Region (SNP) | VAF 53/314 reads (17%) | catalogued as rs781290535; called by muse, mutect2, varscan2
- GINS3 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs897965692; called by muse, mutect2, varscan2
- MCAM | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV104382481; called by muse, mutect2, varscan2
- MED24 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs142219986; called by muse, mutect2, varscan2
- MGAT5 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 118/585 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs756426382; called by muse, mutect2, varscan2
- RTP3 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs757914880, COSV56123922; called by muse, mutect2, varscan2
- SGK2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 90/445 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs756048017; called by muse, mutect2, varscan2
- SMYD4 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 222/273 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs1254683052; called by muse, mutect2, varscan2
- ANO2 | c.1519G>A p.E507K (on ENST00000356134 / NM_001278597.3; = p.E511K on NM_001278596.3) | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP299 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNTNAP5 | c.1378A>T p.N460Y | Missense Mutation (SNP) | VAF 64/500 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- DEF8 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP14 | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 126/401 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- EFCAB8 | c.1872G>C p.K624N | Missense Mutation (SNP) | VAF 80/407 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAM228B | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FBN2 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GABBR1 | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2
- KCNU1 | c.1006G>C p.V336L | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LY75 | c.1952C>G p.P651R | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- MED13 | c.5493A>C p.K1831N | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAT4D | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR10H4 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REELD1 | c.1469A>T p.N490I | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SCAPER | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK5 | c.2633C>G p.P878R | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SSH2 | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 118/195 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ST14 | c.1982A>G p.D661G | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- UBE4A | c.1187A>C p.K396T (on ENST00000252108 / NM_001204077.2; = p.K403T on NM_004788.4) | Missense Mutation (SNP) | VAF 190/514 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- UFL1 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- GRK6 | c.279C>G p.T93= | Silent (SNP) | VAF 75/253 reads (30%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.183C>A p.S61= | Silent (SNP) | VAF 73/400 reads (18%) | called by muse, mutect2, varscan2
- RINL | c.1314T>C p.Y438= (on ENST00000591812 / NM_001195833.2; = p.Y324= on NM_198445.4) | Silent (SNP) | VAF 52/473 reads (11%) | called by muse, mutect2, varscan2
- RYR1 | c.7701G>A p.P2567= | Silent (SNP) | VAF 24/706 reads (3%) | catalogued as rs1420408214, COSV100614201; called by muse, mutect2
- SHISAL2B | c.60G>A p.E20= | Silent (SNP) | VAF 65/327 reads (20%) | catalogued as rs1465423162; called by muse, mutect2, varscan2
- STAM | c.1296G>T p.P432= | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as rs782524823; called by mutect2, varscan2
- TFAP2C | c.960C>A p.V320= | Silent (SNP) | VAF 61/519 reads (12%) | catalogued as COSV52373522; called by mutect2, varscan2
- ZNF521 | c.687C>T p.D229= | Silent (SNP) | VAF 125/397 reads (31%) | catalogued as rs140420623; called by muse, mutect2, varscan2
- AZGP1 | c.338-34G>A | Intron (SNP) | VAF 33/101 reads (33%) | catalogued as rs1307226670; called by muse, mutect2, varscan2
- ERCC1 | c.-7-87G>T | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- MAGI1 | c.2168-87del | Intron (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- RELN | c.6931-16T>A | Intron (SNP) | VAF 75/253 reads (30%) | catalogued as rs1229118503, COSV100633181; called by muse, mutect2, varscan2
- SCNN1G | c.*1G>C | 3'UTR (SNP) | VAF 135/287 reads (47%) | called by muse, mutect2, varscan2
- SMAP1 | c.*1467del | 3'UTR (DEL) | VAF 84/238 reads (35%) | called by mutect2, pindel*, varscan2
- TNRC6B | c.*69G>A | 3'UTR (SNP) | VAF 22/52 reads (42%) | catalogued as rs1401912912; called by mutect2, varscan2
- TSPAN2 | c.*22G>T | 3'UTR (SNP) | VAF 70/370 reads (19%) | called by muse, mutect2, varscan2
